Somatic mutation profile of tumor specimen TCGA-CU-A5W6-01A (aliquot TCGA-CU-A5W6-01A-11D-A289-08) from TCGA case TCGA-CU-A5W6, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 70.4 years (25,706 days).
Specimen TCGA-CU-A5W6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad1a714b-b3fc-43d0-b73b-d21be6038fc9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CU-A5W6-10A (Blood Derived Normal), aliquot TCGA-CU-A5W6-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68134a32-a7d0-4029-a294-c79a66c301e4

The open-access MAF lists 239 somatic variants for this specimen: 182 protein-altering or splice-affecting, 56 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 163, Silent 56, Nonsense Mutation 12, Frame Shift Ins 2, Frame Shift Del 2, Splice Site 2, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXL2 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 34/63 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as CM082718, COSV57725966, COSV57728681; called by muse, mutect2, varscan2
- LDLR | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs144172724, CD045103, CM920408, CM950751; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 21/63 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV59206538, COSV59210925; called by muse, mutect2, varscan2
- AACS | c.1964C>G p.S655W | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs150578262, COSV55539837; called by muse, mutect2, varscan2
- ABCB1 | c.3835C>T p.R1279C | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as rs137996914, COSV99711994; called by muse, varscan2
- ADCY6 | c.2900A>G p.N967S | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as rs985391505, COSV57170017; called by muse, mutect2, varscan2
- ADGRE5 | c.2045G>C p.R682T (on ENST00000242786 / NM_078481.4; = p.R589T on NM_001784.5) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV99660300; called by muse, mutect2
- AHNAK | c.7472G>C p.G2491A | Missense Mutation (SNP) | VAF 76/203 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.163); catalogued as COSV57226730; called by muse, mutect2, varscan2
- ALMS1 | c.8266G>C p.E2756Q | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as COSV52519854; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7499A>G p.N2500S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as rs771254967, COSV51856537; called by muse, mutect2, varscan2
- ANXA6 | c.631C>G p.L211V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100636908; called by muse, mutect2, varscan2
- APBB3 | c.191G>C p.G64A | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as COSV60053921; called by muse, mutect2, varscan2
- AQP10 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV61476024; called by muse, mutect2, varscan2
- ARHGAP35 | c.4130C>T p.S1377F | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); catalogued as COSV101351032; called by muse, mutect2
- ARID1A | c.2769G>A p.M923I | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV61387029; called by muse, mutect2, varscan2
- ASXL2 | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55466319; called by muse, varscan2
- ATAD5 | c.1903G>C p.E635Q | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.262); catalogued as rs1251357946, COSV58977154, COSV58978096; called by muse, mutect2, varscan2
- ATP2B2 | c.39C>A p.N13K | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.995); catalogued as COSV59505857; called by muse, mutect2, varscan2
- ATP2C2 | c.252G>C p.Q84H | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.967); catalogued as COSV52300492; called by muse, mutect2, varscan2
- B3GNT5 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 26/99 reads (26%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV58476783; called by muse, mutect2, varscan2
- B3GNT5 | c.323G>C p.R108T | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58476792; called by muse, mutect2, varscan2
- C10orf88 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.591); catalogued as rs537314570, COSV100925001, COSV64404326; called by muse, mutect2, varscan2
- C12orf60 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV57453070; called by muse, mutect2, varscan2
- C16orf71 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); catalogued as COSV99556315; called by muse, mutect2, varscan2
- CACNA1G | c.3530C>T p.T1177I | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.103); catalogued as COSV61736338; called by muse, mutect2, varscan2
- CAPN9 | c.677G>C p.R226T | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV55238611; called by muse, mutect2, varscan2
- CASKIN2 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs374208140; called by muse, mutect2, varscan2
- CCDC88B | c.3133G>C p.E1045Q | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.941); catalogued as COSV57267760; called by muse, mutect2, varscan2
- CCL28 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as rs750193455, COSV63149936; called by muse, mutect2, varscan2
- CDC6 | c.792G>A p.M264I | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1367355755, COSV52931260; called by muse, mutect2, varscan2
- CDH13 | c.114C>G p.I38M | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as COSV51810282; called by muse, mutect2, varscan2
- CELF2 | c.95C>G p.S32* (on ENST00000416382 / NM_001025077.3; = p.S39* on NM_006561.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 51/235 reads (22%) | catalogued as COSV100257550; called by muse, mutect2, varscan2
- CELSR1 | c.7304C>G p.S2435C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.957); catalogued as COSV53098167; called by muse, varscan2
- CFAP92 | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.559); catalogued as rs746708755, COSV54048619; called by muse, mutect2, varscan2
- CHGB | c.1222G>C p.E408Q | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.138); catalogued as COSV66761528; called by muse, mutect2, varscan2
- CLDN1 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.702); catalogued as COSV55044955; called by muse, mutect2, varscan2
- CLSPN | c.2044C>G p.L682V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); catalogued as COSV52056290; called by muse, mutect2, varscan2
- CMKLR1 | c.339G>C p.K113N (on ENST00000312143 / NM_001142344.2; = p.K111N on NM_004072.3) | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56441394; called by muse, mutect2, varscan2
- CNTN1 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV61644593; called by muse, mutect2, varscan2
- CRELD1 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 25/72 reads (35%) | catalogued as COSV99925789; called by muse, mutect2, varscan2
- CRPPA | c.1156C>G p.Q386E (on ENST00000407010 / NM_001368197.1; = p.Q336E on NM_001101417.4) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV67907137, COSV67908820; called by muse, mutect2
- DAB2IP | c.772G>A p.E258K (on ENST00000408936; = p.E230K on NM_032552.3) | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1564207849, COSV52266529; called by muse, mutect2, varscan2
- DCDC1 | c.2380C>A p.H794N | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.015); catalogued as COSV100663402, COSV100664420; called by muse, mutect2, varscan2
- DDX50 | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV65293198; called by muse, mutect2, varscan2
- DOCK5 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs143551268, COSV52398678; called by muse, mutect2, varscan2
- DOK4 | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs146675149; called by muse, varscan2
- DPF2 | c.643G>T p.G215* | Nonsense Mutation (SNP) | VAF 27/89 reads (30%) | catalogued as COSV99361642; called by muse, mutect2, varscan2
- DPF2 | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV52891039; called by muse, mutect2, varscan2
- ECHDC3 | c.765C>G p.F255L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.642); catalogued as COSV64867880; called by muse, mutect2, varscan2
- EDEM3 | c.1114C>G p.H372D | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58921379, COSV58927292; called by muse, mutect2, varscan2
- ENTPD7 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as rs770686860, COSV65113125; called by muse, mutect2, varscan2
- EPB41L4A | c.1543T>A p.W515R | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54878558; called by muse, mutect2, varscan2
- EVI5 | c.86C>A p.S29Y | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); catalogued as COSV64826999, COSV64829546; called by muse, mutect2, varscan2
- FAM135A | c.1045G>A p.E349K (on ENST00000370479 / NM_001351599.1; = p.E332K on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52057738; called by muse, varscan2
- FAM83E | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.18); catalogued as rs1246953016, COSV52377004; called by muse, mutect2
- FAT3 | c.1471G>A p.V491I | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.06); catalogued as rs376399512; called by muse, mutect2, varscan2
- FLOT2 | c.825C>G p.I275M | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as COSV67529426; called by muse, mutect2, varscan2
- FLT1 | c.3443C>T p.A1148V | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs971646396, COSV56739680; called by muse, mutect2, varscan2
- FLT1 | c.3107T>C p.V1036A | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56739701; called by muse, mutect2, varscan2
- FOXL2 | c.207G>C p.E69D | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.079); catalogued as COSV57726404, COSV57729898; called by muse, mutect2, varscan2
- FTSJ3 | c.868A>T p.I290L | Missense Mutation (SNP) | VAF 116/317 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as COSV59563792; called by muse, mutect2, varscan2
- GALC | c.26C>A p.S9Y | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99729689; called by muse, mutect2, varscan2
- GLIS3 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV60934263; called by muse, mutect2, varscan2
- GLOD5 | c.395G>A p.R132K | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as COSV57489974; called by muse, mutect2, varscan2
- GRIP1 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV54015940, COSV99669888; called by muse, mutect2, varscan2
- GRM2 | c.1039G>T p.E347* | Nonsense Mutation (SNP) | VAF 11/87 reads (13%) | catalogued as COSV99622813; called by muse, mutect2, varscan2
- HDAC6 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.89); catalogued as COSV61930298; called by muse, mutect2, varscan2
- HDAC6 | c.1294G>C p.E432Q | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated (0.41); PolyPhen benign (0.102); catalogued as COSV61930312; called by muse, varscan2
- HDAC6 | c.1686G>C p.E562D | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV61930320; called by muse, mutect2, varscan2
- HDAC6 | c.2114G>A p.W705* | Nonsense Mutation (SNP) | VAF 11/15 reads (73%) | catalogued as COSV100490814; called by muse, mutect2, varscan2
- HERC2 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs551301503, COSV55345452; called by muse, mutect2, varscan2
- IGSF9B | c.3544C>T p.R1182W | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs765118637, COSV58063635; called by muse, mutect2, varscan2
- INTS1 | c.5083C>G p.L1695V | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV67177141; called by muse, mutect2, varscan2
- IRF5 | c.192C>G p.F64L | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50860451; called by muse, mutect2, varscan2
- JAK3 | c.621C>A p.F207L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.406); catalogued as COSV71687320; called by muse, varscan2
- KASH5 | c.1082G>C p.R361T | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV71358392; called by muse, mutect2, varscan2
- KAT5 | c.1305G>C p.E435D | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.123); catalogued as COSV57730463; called by muse, mutect2, varscan2
- KIF18A | c.544G>C p.D182H | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54186950; called by muse, mutect2, varscan2
- KPRP | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 82/266 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.124); catalogued as COSV64222788; called by muse, mutect2, varscan2
- KRTAP10-6 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 66/308 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV59967485, COSV59976661; called by muse, mutect2, varscan2
- LCP1 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100550083, COSV59942747; called by muse, mutect2, varscan2
- LYPD3 | c.36G>A p.M12I | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV54989560; called by muse, mutect2, varscan2
- MAP3K7 | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV65225708; called by muse, mutect2, varscan2
- MAP7D1 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.101); catalogued as rs138447994, COSV60215129; called by muse, mutect2, varscan2
- MARF1 | c.259C>T p.Q87* | Nonsense Mutation (SNP) | VAF 21/109 reads (19%) | catalogued as rs1288493515, COSV60022661; called by muse, mutect2, varscan2
- MED25 | c.1320G>T p.K440N | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.87); PolyPhen benign (0.057); catalogued as COSV57206802; called by muse, mutect2, varscan2
- MIF | c.9G>A p.M3I | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV53159139; called by muse, mutect2, varscan2
- MRPS9 | c.565dup p.T189Nfs*14 | Frame Shift Ins (INS) | VAF 9/48 reads (19%) | catalogued as rs1356455531; called by mutect2, pindel, varscan2
- MRTFA | c.1354-2A>T p.X452_splice | Splice Site (SNP) | VAF 10/42 reads (24%) | catalogued as COSV62936206; called by muse, mutect2
- MTCL1 | c.4210G>A p.E1404K (on ENST00000306329 / NM_001378206.1; = p.E1085K on NM_015210.4) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.823); catalogued as COSV100093129, COSV60410727; called by muse, mutect2
- MTMR4 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as COSV60200923; called by muse, mutect2, varscan2
- NCOR1 | c.3211C>T p.Q1071* | Nonsense Mutation (SNP) | VAF 19/43 reads (44%) | catalogued as COSV99063232; called by muse, mutect2, varscan2
- NEK10 | c.2855C>T p.S952L | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV55363971; called by muse, mutect2, varscan2
- NEK5 | c.1487C>G p.S496* | Nonsense Mutation (SNP) | VAF 24/59 reads (41%) | catalogued as COSV100839228; called by muse, mutect2, varscan2
- NLRP8 | c.2377C>G p.L793V | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); catalogued as COSV52592748, COSV52593623; called by muse, mutect2, varscan2
- NOS3 | c.3400G>A p.E1134K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0.098); catalogued as COSV52494600; called by muse, mutect2, varscan2
- NPHS2 | c.989T>C p.L330P | Missense Mutation (SNP) | VAF 85/136 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62636349; called by muse, mutect2, varscan2
- NPNT | c.1529C>A p.A510D | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59756569; called by muse, mutect2, varscan2
- NUBP2 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV51908087; called by muse, mutect2, varscan2
- OCA2 | c.1021G>A p.V341I | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs368159473; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR5K2 | c.771C>A p.F257L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.363); catalogued as COSV101415994, COSV71143463; called by muse, mutect2, varscan2
- OR5M8 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.775); catalogued as rs376477019; called by muse, mutect2, varscan2
- OR5W2 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV60615657; called by muse, mutect2, varscan2
- PCDHB3 | c.1787C>T p.S596L | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.778); catalogued as rs1554272567, COSV50619820; called by muse, mutect2, varscan2
- PDS5A | c.3721G>A p.V1241I | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.006); catalogued as rs747694338, COSV57830320; called by muse, mutect2, varscan2
- PFDN2 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.27); catalogued as rs921101282, COSV63510248; called by muse, mutect2, varscan2
- PIBF1 | c.1745G>C p.R582T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100411922, COSV58327399; called by muse, varscan2
- PIK3CB | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as rs545189148, COSV56689386; called by muse, mutect2, varscan2
- PKP4 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV61580098; called by muse, mutect2, varscan2
- PLOD3 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV56185444; called by muse, mutect2, varscan2
- PRAMEF14 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.14); catalogued as rs1553125341, COSV58050180; called by muse, mutect2, varscan2
- PREX1 | c.1852G>A p.V618M | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as COSV64255893; called by muse, mutect2, varscan2
- PROC | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52168016; called by muse, mutect2
- PSG6 | c.641A>G p.Y214C | Missense Mutation (SNP) | VAF 175/587 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51836690; called by muse, mutect2, varscan2
- PSMC3 | c.488C>T p.T163M | Missense Mutation (SNP) | VAF 76/158 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.563); catalogued as rs1273113578, COSV54082508; called by muse, mutect2, varscan2
- PTGS1 | c.445C>A p.R149S | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99793180; called by muse, mutect2
- PTH1R | c.1766G>A p.W589* | Nonsense Mutation (SNP) | VAF 77/266 reads (29%) | catalogued as COSV100480966; called by muse, mutect2, varscan2
- PTPMT1 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.408); catalogued as COSV58597791; called by muse, mutect2, varscan2
- PWWP2A | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.012); catalogued as COSV61047683; called by muse, mutect2, varscan2
- QRICH2 | c.4967C>T p.S1656L | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs757542078, COSV53150823; called by muse, mutect2, varscan2
- RASGRF2 | c.6G>C p.Q2H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV54137683; called by muse, mutect2, varscan2
- RBM45 | c.805A>G p.I269V (on ENST00000616198 / NM_001365579.1; = p.I267V on NM_152945.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as rs200524633, COSV53722268; called by muse, mutect2, varscan2
- RGS1 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66506294; called by muse, mutect2, varscan2
- RIC1 | c.1738C>T p.H580Y | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs544522535, COSV52614367; called by muse, mutect2, varscan2
- RIC8A | c.1204G>A p.E402K (on ENST00000526104 / NM_001286134.1; = p.E408K on NM_021932.5) | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV57343991; called by muse, mutect2, varscan2
- RIC8A | c.1333G>A p.E445K (on ENST00000526104 / NM_001286134.1; = p.E451K on NM_021932.5) | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV57342323; called by muse, mutect2, varscan2
- RPSA | c.230T>C p.I77T | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.398); catalogued as rs893556660, COSV57192311; called by muse, mutect2, varscan2
- RSAD1 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV51957048; called by muse, varscan2
- RSF1 | c.2621C>T p.S874L | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV57843773; called by muse, mutect2, varscan2
- RTN2 | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as rs761153006, COSV55595707; called by muse, mutect2, varscan2
- RYR3 | c.4370T>A p.F1457Y | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV66805646; called by muse, mutect2, varscan2
- SASH1 | c.3220G>A p.G1074S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.349); catalogued as rs775841453, COSV66564907; called by muse, mutect2, varscan2
- SBK2 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.017); catalogued as COSV60015692, COSV99067476; called by muse, mutect2, varscan2
- SCRIB | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 68/227 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs137872634, COSV57592438; called by muse, mutect2, varscan2
- SEPTIN4 | c.1559T>C p.L520P | Missense Mutation (SNP) | VAF 53/271 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV58728881; called by muse, mutect2, varscan2
- SH2D2A | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 31/339 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63885384; called by muse, mutect2
- SH2D4A | c.1196C>G p.S399C | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56124543, COSV99745310; called by muse, mutect2, varscan2
- SLC28A3 | c.380G>A p.R127K | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV66154691; called by muse, mutect2, varscan2
- SLC8A1 | c.278C>G p.S93C | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60487770, COSV60493960; called by muse, mutect2, varscan2
- SLC9B1 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs754738344, COSV56467872, COSV56469127; called by muse, mutect2, varscan2
- SLFN13 | c.1503G>T p.M501I | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99539986, COSV99539990, COSV99540546; called by muse, mutect2, varscan2
- SLIT2 | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56591204; called by muse, mutect2, varscan2
- SNW1 | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55056293; called by muse, varscan2
- SNX1 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.441); catalogued as COSV56039743; called by muse, mutect2, varscan2
- SNX21 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs760956420, COSV61132434; called by muse, mutect2, varscan2
- SP100 | c.2206G>C p.D736H | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as COSV50999946; called by muse, mutect2, varscan2
- SSH3 | c.1381C>T p.Q461* | Nonsense Mutation (SNP) | VAF 32/123 reads (26%) | catalogued as COSV100354555; called by muse, mutect2, varscan2
- STH | c.121C>T p.Q41* | Nonsense Mutation (SNP) | VAF 39/88 reads (44%) | catalogued as COSV52249441; called by muse, mutect2, varscan2
- SUPT3H | c.742C>T p.L248F (on ENST00000371460 / NM_181356.3; = p.L237F on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV60948883; called by muse, mutect2, varscan2
- SVIL | c.2270C>G p.S757C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as COSV63447315; called by muse, mutect2, varscan2
- TBC1D10A | c.522C>A p.H174Q | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.398); catalogued as COSV53165623; called by muse, mutect2, varscan2
- TCTA | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); catalogued as COSV55534385, COSV99648811; called by muse, mutect2, varscan2
- TET1 | c.733C>G p.Q245E | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV101018233, COSV65388687; called by muse, varscan2
- TET1 | c.805C>G p.Q269E | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV65388692; called by muse, varscan2
- TJP3 | c.2537C>T p.S846L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs747055951, COSV99516057; called by muse, varscan2
- TLR5 | c.1321C>G p.L441V | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.059); catalogued as COSV60560487; called by muse, mutect2, varscan2
- TOP2A | c.4102G>C p.E1368Q | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.069); catalogued as COSV101352291, COSV68503204; called by muse, mutect2, varscan2
- TOP2A | c.3694G>A p.E1232K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.138); catalogued as COSV68502966; called by mutect2, varscan2
- TRIM37 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.01); catalogued as COSV51887928; called by muse, mutect2, varscan2
- TTN | c.4063C>T p.L1355F (on ENST00000591111; = p.L1309F on NM_003319.4) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | PolyPhen benign (0.031); catalogued as COSV60289335; called by muse, mutect2, varscan2
- TULP4 | c.3301G>C p.E1101Q | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); catalogued as COSV65572233; called by muse, mutect2, varscan2
- VEZF1 | c.1506G>A p.M502I | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as COSV51969996; called by muse, mutect2, varscan2
- VPS50 | c.2695G>C p.D899H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.998); catalogued as COSV59922284; called by muse, mutect2, varscan2
- WDR19 | c.1869G>C p.Q623H | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as COSV56469163; called by muse, mutect2, varscan2
- WRN | c.1787C>G p.S596C | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.186); catalogued as COSV53305996, COSV99989781; called by muse, mutect2, varscan2
- YTHDF1 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV64833816; called by muse, mutect2, varscan2
- ZC3H12C | c.2057G>C p.R686T | Missense Mutation (SNP) | VAF 122/438 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV53712321; called by muse, mutect2, varscan2
- ZCWPW2 | c.730A>G p.K244E | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV101074853; called by muse, mutect2
- ZFYVE26 | c.4659G>C p.M1553I | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV61332839; called by muse, mutect2, varscan2
- ZNF281 | c.2343C>G p.F781L | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV54169374; called by muse, mutect2, varscan2
- ZNF282 | c.1534G>T p.G512C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.482); catalogued as COSV50482823; called by muse, mutect2, varscan2
- ZNF296 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs139536353, COSV55519850; called by muse, mutect2, varscan2
- ZNF441 | c.2012A>G p.Y671C | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs138221659; called by muse, mutect2, varscan2
- ZNF513 | c.1520C>A p.S507Y | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV52009955; called by muse, mutect2, varscan2
- ZNF608 | c.4234G>T p.E1412* | Nonsense Mutation (SNP) | VAF 19/80 reads (24%) | catalogued as COSV100101627; called by muse, mutect2, varscan2
- ZNF813 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV67177820; called by muse, mutect2, varscan2
- EP300 | c.3262-10_3275del p.X1088_splice | Splice Site (DEL) | VAF 5/41 reads (12%) | called by mutect2, pindel
- KMT2D | c.7815_7830del p.G2606Afs*80 | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | called by mutect2, pindel, varscan2
- RARG | c.545dup p.S183Efs*50 | Frame Shift Ins (INS) | VAF 21/95 reads (22%) | called by mutect2, pindel, varscan2
- SIGLEC6 | c.1259_1263del p.D420Afs*24 | Frame Shift Del (DEL) | VAF 86/278 reads (31%) | called by mutect2, pindel, varscan2
- SRCIN1 | c.2696C>A p.P899H (on ENST00000621492; = p.P865H on NM_025248.3) | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ACAN | c.1191G>A p.V397= | Silent (SNP) | VAF 30/105 reads (29%) | catalogued as COSV61367906; called by muse, mutect2, varscan2
- ADD1 | c.2037C>T p.P679= | Silent (SNP) | VAF 50/180 reads (28%) | catalogued as rs373749278; called by muse, mutect2, varscan2
- ALDH16A1 | c.921C>T p.L307= | Silent (SNP) | VAF 83/212 reads (39%) | catalogued as COSV53195519, COSV53196155; called by muse, mutect2, varscan2
- ANKRD44 | c.678G>A p.L226= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as COSV56564000; called by muse, mutect2, varscan2
- AP1S2 | c.219G>A p.Q73= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV61307139; called by muse, mutect2, varscan2
- APC2 | c.84G>A p.E28= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV52021424; called by muse, mutect2, varscan2
- APH1B | c.483C>T p.F161= | Silent (SNP) | VAF 101/314 reads (32%) | catalogued as COSV56015198; called by muse, mutect2, varscan2
- CACNA2D3 | c.1461G>A p.Q487= | Silent (SNP) | VAF 69/242 reads (29%) | catalogued as rs1291550567, COSV55573697, COSV55589340; called by muse, mutect2, varscan2
- CCDC180 | c.2424C>T p.I808= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as COSV63834323; called by muse, mutect2, varscan2
- CELSR1 | c.5739G>T p.L1913= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV53098186; called by muse, mutect2, varscan2
- CFAP157 | c.381C>A p.R127= | Silent (SNP) | VAF 34/54 reads (63%) | catalogued as COSV58854180; called by muse, mutect2, varscan2
- CNTN4 | c.2373C>T p.T791= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV61879637; called by muse, mutect2, varscan2
- COG1 | c.1110C>G p.L370= | Silent (SNP) | VAF 49/175 reads (28%) | catalogued as COSV55431616, COSV55432432; called by muse, mutect2, varscan2
- CYHR1 | c.81G>A p.V27= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV56762642; called by muse, mutect2, varscan2
- DUOX2 | c.1815C>T p.L605= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV101199754; called by muse, mutect2
- FBXO9 | c.714G>A p.L238= | Silent (SNP) | VAF 32/132 reads (24%) | catalogued as COSV55056930; called by muse, mutect2, varscan2
- FREM2 | c.1875C>T p.L625= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs1489516590, COSV54849269; called by muse, mutect2, varscan2
- FRYL | c.252C>T p.R84= | Silent (SNP) | VAF 33/174 reads (19%) | catalogued as rs780707687, COSV51959186; called by muse, mutect2, varscan2
- FYB1 | c.63C>T p.F21= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV60954819; called by muse, mutect2, varscan2
- FYCO1 | c.3558C>T p.F1186= | Silent (SNP) | VAF 76/194 reads (39%) | catalogued as COSV56118855; called by muse, mutect2, varscan2
- GIPC3 | c.417C>T p.I139= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs1454939272, COSV59260572; called by muse, mutect2, varscan2
- GRIA4 | c.72G>A p.P24= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs957571829, COSV56915495; called by muse, mutect2, varscan2
- HMGN2 | c.51G>T p.V17= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV52578328; called by muse, mutect2, varscan2
- IDS | c.219C>T p.L73= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs1803784, CD056460, CD128215, COSV61711679; called by muse, mutect2, varscan2
- IRF2BPL | c.1071G>C p.L357= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV53148628; called by muse, mutect2, varscan2
- JAK3 | c.837C>T p.I279= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs1396530798, COSV71687317; called by muse, mutect2, varscan2
- JAK3 | c.462C>T p.L154= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV71687324; called by muse, varscan2
- JAK3 | c.210C>G p.L70= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV71687334; called by muse, mutect2, varscan2
- KCNH6 | c.1893C>G p.L631= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV59006945; called by muse, mutect2, varscan2
- KLHL24 | c.1287C>T p.S429= | Silent (SNP) | VAF 37/141 reads (26%) | catalogued as COSV54428339; called by muse, mutect2, varscan2
- LANCL1 | c.987C>A p.A329= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV52066769; called by muse, mutect2
- LARP6 | c.672T>C p.F224= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV54582118; called by muse, mutect2
- MARF1 | c.432C>T p.I144= | Silent (SNP) | VAF 43/230 reads (19%) | catalogued as COSV60028000; called by muse, mutect2, varscan2
- MC5R | c.582C>T p.F194= | Silent (SNP) | VAF 278/746 reads (37%) | catalogued as COSV61255533; called by muse, mutect2, varscan2
- MED25 | c.1398G>C p.R466= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV57206815; called by muse, mutect2, varscan2
- MTCL1 | c.4212G>A p.E1404= (on ENST00000306329 / NM_001378206.1; = p.E1085= on NM_015210.4) | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs750833884, COSV60407848; called by muse, mutect2
- MVB12A | c.594G>A p.R198= | Silent (SNP) | VAF 34/126 reads (27%) | catalogued as COSV57679611; called by muse, mutect2, varscan2
- NFIX | c.57G>A p.L19= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV62180278; called by muse, varscan2
- NUDT5 | c.192C>T p.V64= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV66718943; called by muse, mutect2, varscan2
- PCDHA12 | c.2106C>A p.I702= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as rs782777600, COSV56538591; called by muse, mutect2, varscan2
- PCDHAC2 | c.720G>A p.T240= | Silent (SNP) | VAF 45/137 reads (33%) | catalogued as rs782309199, COSV53853158; called by muse, mutect2, varscan2
- PCDHB2 | c.657C>T p.G219= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV52035339, COSV52036061; called by muse, mutect2, varscan2
- PCDHB5 | c.1509C>T p.V503= | Silent (SNP) | VAF 99/379 reads (26%) | catalogued as COSV50665452; called by muse, mutect2, varscan2
- PNMA1 | c.1047G>A p.L349= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV99678878; called by mutect2, varscan2
- PPP2R5B | c.435G>A p.E145= | Silent (SNP) | VAF 35/101 reads (35%) | catalogued as COSV51212489; called by muse, mutect2, varscan2
- PWWP2A | c.384G>A p.E128= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV61047699; called by muse, mutect2, varscan2
- SKIL | c.1590C>T p.I530= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV52058297; called by muse, mutect2, varscan2
- SPACA3 | c.229C>T p.L77= | Silent (SNP) | VAF 39/108 reads (36%) | catalogued as COSV52192402; called by muse, mutect2, varscan2
- SPDYE5 | c.966G>A p.P322= | Silent (SNP) | VAF 100/459 reads (22%) | catalogued as rs782181392; called by muse, mutect2
- SRP68 | c.384G>C p.L128= | Silent (SNP) | VAF 50/199 reads (25%) | catalogued as COSV57164403; called by muse, mutect2, varscan2
- TEAD2 | c.1290C>G p.V430= | Silent (SNP) | VAF 39/128 reads (30%) | catalogued as COSV60545171; called by muse, mutect2, varscan2
- TF | c.1098G>A p.L366= | Silent (SNP) | VAF 64/218 reads (29%) | catalogued as COSV53923511; called by muse, mutect2, varscan2
- TRIM42 | c.1956C>T p.L652= | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as rs777191054, COSV53886243; called by muse, mutect2, varscan2
- TUFT1 | c.687C>T p.V229= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs762009985, COSV61950168; called by muse, mutect2, varscan2
- TUT7 | c.1170T>C p.H390= | Silent (SNP) | VAF 67/121 reads (55%) | catalogued as COSV52898325; called by muse, mutect2, varscan2
- XPO5 | c.2619C>T p.L873= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as rs193195408, COSV54834101; called by muse, mutect2, varscan2
- RTBDN | chr19:12834813 G>T | 5'Flank (SNP) | VAF 38/96 reads (40%) | catalogued as COSV99262900; called by muse, mutect2, varscan2
